Somatic mutation profile of tumor specimen 0DG5AM from CCDI case PBBSYU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.6 years (3,524 days).
Specimen 0DG5AM: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54da90bb-09ab-47f2-bb35-b0e15f97da8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG5AB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4df89ee-35e3-458f-a447-97854bba92a2

The open-access MAF lists 69 somatic variants for this specimen: 44 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Intron 5, Frame Shift Del 2, 5'UTR 2, Splice Region 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- APOL1 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.167); catalogued as COSV100046295; called by muse, mutect2
- APP | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 109/348 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs751737465; called by muse, varscan2
- C12orf71 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 79/303 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs374505766, COSV70282633; called by muse, mutect2, varscan2
- C1QTNF7 | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs746533641, COSV99765037; called by muse, varscan2
- CYP11B1 | c.1201-1G>T p.X401_splice | Splice Site (SNP) | VAF 90/693 reads (13%) | catalogued as COSV52826918; called by muse, varscan2
- CYP11B2 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 72/600 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs780112807, COSV59995495; called by muse, mutect2, varscan2
- FBXO42 | c.1922G>T p.C641F | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV65046333; called by muse, mutect2, varscan2
- GRIK1 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766117519, COSV100516584; called by muse, mutect2, varscan2
- HMGXB3 | c.1796dup p.V601Sfs*24 (on ENST00000613459; = p.V355Sfs*24 on NM_014983.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/135 reads (12%) | catalogued as rs771153430; called by mutect2, varscan2
- IFT122 | c.1663G>A p.A555T (on ENST00000348417 / NM_052989.3; = p.A496T on NM_018262.4) | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs757574680; called by muse, mutect2, varscan2
- MARF1 | c.2477T>G p.L826R | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60023418; called by muse, mutect2, varscan2
- PBDC1 | c.59A>G p.H20R | Missense Mutation (SNP) | VAF 64/68 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1450375621; called by muse, mutect2, varscan2
- PCNX1 | c.4231C>A p.Q1411K | Missense Mutation (SNP) | VAF 139/299 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53089250; called by muse, mutect2, varscan2
- PRAMEF2 | c.794G>T p.R265M | Missense Mutation (SNP) | VAF 132/319 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs1186861552; called by muse, mutect2, varscan2
- SLC26A7 | c.1357G>T p.A453S | Missense Mutation (SNP) | VAF 101/884 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52607024; called by muse, varscan2
- SLC4A3 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 124/432 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs548729264; called by muse, mutect2, varscan2
- SPATA32 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 142/335 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.348); catalogued as rs772027527; called by muse, mutect2, varscan2
- SPCS1 | c.413G>A p.R138H (on ENST00000233025; = p.R71H on NM_014041.5) | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172861317, COSV51776939; called by muse, mutect2, varscan2
- TEX13D | c.1086G>C p.M362I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs1364180197, COSV69794684; called by muse, mutect2, varscan2
- TEX13D | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV69794686; called by muse, mutect2, varscan2
- TTC30B | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs368765664; called by muse, varscan2
- ARID1A | c.2623del p.M875Cfs*16 | Frame Shift Del (DEL) | VAF 34/79 reads (43%) | called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 15/112 reads (13%) | called by muse, varscan2
- CECR2 | c.532C>G p.L178V (on ENST00000342247 / NM_001290047.2; = p.L15V on NM_001290046.1) | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- DNAH11 | c.8569G>T p.G2857W | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.11060A>G p.K3687R | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- EDARADD | c.601G>C p.E201Q (on ENST00000334232 / NM_145861.4; = p.E191Q on NM_080738.4) | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FLT3 | c.2654G>A p.G885D | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIF27 | c.1856G>T p.G619V | Missense Mutation (SNP) | VAF 131/322 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC3 | c.2834A>T p.Q945L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by mutect2, varscan2
- LCE1B | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFN2 | c.1613A>G p.Q538R | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- NEURL3 | c.701del p.T234Rfs*11 | Frame Shift Del (DEL) | VAF 90/269 reads (33%) | called by mutect2, varscan2
- NOX4 | c.809G>C p.C270S | Missense Mutation (SNP) | VAF 95/407 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- NPY1R | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35A3 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 145/336 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- SPATA20 | c.825C>A p.S275R (on ENST00000356488 / NM_001258372.1; = p.S291R on NM_022827.4) | Missense Mutation (SNP) | VAF 185/440 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SPRN | c.333C>G p.N111K | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TIGD5 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 53/544 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2
- USP17L4 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); called by muse, varscan2
- ZFHX4 | c.5561C>A p.S1854Y | Missense Mutation (SNP) | VAF 195/762 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ZNF540 | c.1687C>G p.R563G | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCK1 | c.312C>T p.D104= | Silent (SNP) | VAF 59/243 reads (24%) | catalogued as rs1184733695; called by muse, mutect2, varscan2
- ADCK5 | c.1419G>T p.L473= | Silent (SNP) | VAF 123/783 reads (16%) | called by muse, mutect2, varscan2
- ADGRG1 | c.984C>T p.P328= | Silent (SNP) | VAF 75/188 reads (40%) | catalogued as rs535653186; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1167537044; called by muse, varscan2
- CHD6 | c.1500T>C p.L500= | Silent (SNP) | VAF 16/370 reads (4%) | called by muse, mutect2
- DNAH3 | c.1854T>C p.D618= | Silent (SNP) | VAF 73/192 reads (38%) | called by muse, mutect2, varscan2
- MIP | c.489C>T p.A163= | Silent (SNP) | VAF 86/311 reads (28%) | catalogued as rs543406345; called by muse, mutect2, varscan2
- NF1 | c.3748C>A p.R1250= | Silent (SNP) | VAF 81/207 reads (39%) | catalogued as CS1512932, COSV62203418; called by muse, mutect2, varscan2
- OPN5 | c.357A>T p.G119= | Silent (SNP) | VAF 84/219 reads (38%) | called by muse, mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, varscan2
- PLXNA1 | c.141C>T p.S47= | Silent (SNP) | VAF 55/108 reads (51%) | catalogued as rs781271756; called by muse, mutect2, varscan2
- PRSS38 | c.51C>A p.G17= | Silent (SNP) | VAF 97/197 reads (49%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.490C>T p.L164= | Silent (SNP) | VAF 56/490 reads (11%) | catalogued as rs1376419773; called by muse, varscan2
- TTC30B | c.621A>G p.A207= | Silent (SNP) | VAF 30/296 reads (10%) | catalogued as rs750265989; called by muse, varscan2
- ZBED4 | c.2475G>A p.V825= | Silent (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- ZNF800 | c.399A>G p.L133= | Silent (SNP) | VAF 128/470 reads (27%) | called by muse, varscan2
- DDX60 | c.4270-54T>A | Intron (SNP) | VAF 14/56 reads (25%) | called by muse, varscan2
- DNM2 | c.1196+48C>T | Intron (SNP) | VAF 27/74 reads (36%) | catalogued as rs777759224; called by muse, mutect2, varscan2
- KCTD8 | c.-45G>C | 5'UTR (SNP) | VAF 72/124 reads (58%) | catalogued as rs767232479, COSV100759512; called by muse, mutect2, varscan2
- MUC19 | n.11710A>T | RNA (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- PLPP5 | c.*1083G>T | 3'UTR (SNP) | VAF 116/966 reads (12%) | called by mutect2, varscan2
- PTPN5 | c.98-20G>A | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as rs377652164; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- RPL3 | c.366-58G>C | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs774315203; called by mutect2, varscan2
- USP40 | c.2381-58G>T | Intron (SNP) | VAF 18/106 reads (17%) | called by muse, varscan2
